CCDI case PBCCFA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/139271f9-43e4-41c3-b832-9be1aba3afa8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,076 days).

Biospecimens (2 samples)
- Sample 0DNYNL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNYO0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
